Somatic mutation profile of tumor specimen TCGA-EK-A2PM-01A (aliquot TCGA-EK-A2PM-01A-11D-A18J-09) from TCGA case TCGA-EK-A2PM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 81.4 years (29,747 days).
Specimen TCGA-EK-A2PM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18a910ad-465b-4527-b4c7-14020debe158.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2PM-10A (Blood Derived Normal), aliquot TCGA-EK-A2PM-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01c63f4c-056c-4520-ac39-53bd51e7bc6a

The open-access MAF lists 338 somatic variants for this specimen: 246 protein-altering or splice-affecting, 80 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 210, Silent 80, Nonsense Mutation 18, Splice Site 8, Intron 5, Frame Shift Del 4, Splice Region 3, 3'UTR 3, In Frame Del 3, 5'UTR 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 8/9 reads (89%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); catalogued as CM034218, CM095540, COSV58683071, COSV58683670; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.1027-1G>T p.X343_splice | Splice Site (SNP) | VAF 19/32 reads (59%) | hotspot (GDC flag); catalogued as CS1413088, COSV64290834, COSV64293694, COSV64298429; called by muse, mutect2, varscan2
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 23/29 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.4117G>A p.E1373K | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as rs201375015, COSV52219205, COSV52227710; called by muse, mutect2, varscan2
- AC006059.2 | c.134A>T p.Q45L | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59606325; called by muse, mutect2
- ACTN3 | c.847A>T p.N283Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101557809; called by muse, mutect2, varscan2
- ADAMTS13 | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.716); catalogued as rs1554791509, COSV63020793; called by muse, mutect2, varscan2
- ADGRV1 | c.11806G>A p.V3936I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs759082660, COSV67982214; called by muse, mutect2, varscan2
- AFF3 | c.1064G>A p.S355N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV57848809; called by muse, mutect2, varscan2
- AHCTF1 | c.1495C>G p.P499A (on ENST00000366508; = p.P473A on NM_015446.5) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV58248060; called by muse, mutect2, varscan2
- AKAP4 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62074069; called by muse, mutect2, varscan2
- AMBRA1 | c.1331C>T p.S444L (on ENST00000458649 / NM_001367468.1; = p.S354L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs139222125, COSV100095853; called by muse, mutect2, varscan2
- ANKRD11 | c.3545G>A p.R1182K | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56358342; called by muse, mutect2, varscan2
- ANTXR1 | c.588T>A p.D196E | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.036); catalogued as COSV58011598; called by muse, mutect2, varscan2
- ANTXR1 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.299); catalogued as COSV58011622; called by muse, mutect2, varscan2
- AOC1 | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 68/84 reads (81%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs756751670, COSV62867754, COSV99054991; called by muse, mutect2, varscan2
- AP4B1 | c.1900A>T p.T634S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as COSV56724157; called by muse, mutect2, varscan2
- APLF | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58143759; called by muse, mutect2
- ARAP3 | c.3748C>G p.L1250V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53349729; called by muse, mutect2, varscan2
- ARPP21 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV51794891; called by muse, mutect2, varscan2
- ATG16L2 | c.1470C>T p.S490= | Splice Region (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100352202; called by muse, mutect2, varscan2
- ATP10B | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV58778263; called by muse, mutect2, varscan2
- B3GNT5 | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV58475707; called by muse, mutect2, varscan2
- BAZ1B | c.4306C>G p.L1436V | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT tolerated (0.55); PolyPhen benign (0.039); catalogued as COSV59989977; called by muse, mutect2, varscan2
- BRIP1 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.106); catalogued as rs1279870189, COSV51996976; called by muse, mutect2, varscan2
- BTBD8 | c.1058G>T p.R353I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV61545827; called by muse, mutect2, varscan2
- BTD | c.1336C>G p.L446V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as COSV57728397; called by muse, mutect2
- C12orf40 | c.1086G>C p.L362F | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61130755; called by muse, mutect2, varscan2
- C1orf112 | c.1184C>G p.S395C | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV53677649; called by muse, mutect2, varscan2
- C8orf34 | c.1486C>T p.H496Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV57400471; called by muse, mutect2
- CACNA1E | c.2555G>A p.R852H | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.215); catalogued as rs538192254, COSV62387759; called by muse, mutect2, varscan2
- CADPS | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs768666285, COSV51873631; called by muse, mutect2, varscan2
- CAMK2A | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1439139668, COSV62245806; called by muse, mutect2, varscan2
- CASD1 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51971579; called by muse, mutect2, varscan2
- CBLL1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV56028513; called by muse, mutect2, varscan2
- CCDC74A | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs749834588, COSV54605937; called by muse, mutect2, varscan2
- CD79B | c.206G>C p.S69T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV50076565; called by muse, mutect2, varscan2
- CEP192 | c.2981C>G p.S994C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100381413, COSV58062094; called by muse, mutect2, varscan2
- CES1 | c.80A>T p.D27V | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.621); catalogued as COSV62086270; called by muse, varscan2
- CES1 | c.77T>A p.V26E | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62086276; called by muse, varscan2
- CFTR | c.3343A>G p.T1115A | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV50045520; called by muse, mutect2, varscan2
- CHD8 | c.6457G>C p.E2153Q (on ENST00000646647 / NM_001170629.2; = p.E1874Q on NM_020920.4) | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.26); PolyPhen benign (0.346); catalogued as COSV63036625; called by muse, mutect2, varscan2
- CHI3L2 | c.369A>T p.E123D | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV63873794; called by muse, mutect2, varscan2
- CLEC3B | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56109553; called by muse, mutect2, varscan2
- CLNS1A | c.192T>A p.H64Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV54439700; called by muse, mutect2, varscan2
- CMSS1 | c.65-1G>A p.X22_splice | Splice Site (SNP) | VAF 28/51 reads (55%) | catalogued as COSV70436308; called by muse, mutect2, varscan2
- CNTN3 | c.333C>A p.S111R | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55167079; called by muse, mutect2, varscan2
- CNTN5 | c.854C>G p.T285R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54297226, COSV54327473; called by muse, mutect2
- COL11A1 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV62178205; called by muse, mutect2, varscan2
- COL2A1 | c.267C>A p.C89* | Nonsense Mutation (SNP) | VAF 20/32 reads (63%) | catalogued as COSV61529296; called by muse, mutect2, varscan2
- COL3A1 | c.4189G>A p.E1397K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs768168922, COSV58585080; called by muse, mutect2, varscan2
- COL4A4 | c.3877G>A p.D1293N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV61630909; called by muse, mutect2, varscan2
- COL4A5 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.867); catalogued as rs771538814, COSV60356642; called by muse, mutect2, varscan2
- COL7A1 | c.7882C>T p.R2628W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs376588113, CM107557; called by muse, mutect2, varscan2
- COL7A1 | c.6318A>T p.E2106D | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV60393438; called by muse, mutect2, varscan2
- CORO2A | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV59662678; called by muse, mutect2, varscan2
- CUX2 | c.1034A>G p.K345R | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV55628332; called by muse, mutect2, varscan2
- CYP1A1 | c.849C>A p.D283E | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV65696869; called by muse, mutect2, varscan2
- CYP4F11 | c.1030C>T p.L344F | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs376221111; called by muse, mutect2, varscan2
- DDX53 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.327); catalogued as COSV60068741; called by muse, mutect2, varscan2
- DLG5 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64947410; called by muse, mutect2, varscan2
- DNAH10 | c.10988C>A p.T3663K (on ENST00000409039; = p.T3602K on NM_207437.3) | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as COSV68990834, COSV99075626; called by muse, mutect2, varscan2
- DNAH17 | c.6341T>G p.L2114R | Missense Mutation (SNP) | VAF 61/76 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67751690; called by muse, mutect2, varscan2
- DNAH8 | c.3022C>T p.Q1008* | Nonsense Mutation (SNP) | VAF 79/150 reads (53%) | catalogued as COSV59435411; called by muse, mutect2, varscan2
- DOCK8 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1212097357, COSV66636412; called by muse, mutect2, varscan2
- DPP10 | c.1999C>T p.L667F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV59677327; called by muse, mutect2
- DRP2 | c.1527G>T p.K509N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100871812; called by muse, mutect2, varscan2
- DSCAM | c.3686C>G p.P1229R | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV68024068; called by muse, mutect2, varscan2
- DTX3L | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56143805; called by muse, mutect2, varscan2
- EIF3G | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV53457871; called by muse, mutect2, varscan2
- ENTR1 | c.1165C>T p.Q389* (on ENST00000357365 / NM_001039707.2; = p.Q366* on NM_006643.4) | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV53741074; called by muse, mutect2, varscan2
- ENTR1 | c.317C>G p.A106G (on ENST00000357365 / NM_001039707.2; = p.A83G on NM_006643.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV53741085; called by muse, mutect2, varscan2
- EP300 | c.3849G>T p.R1283S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV54329865; called by muse, mutect2, varscan2
- EP400 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV57768395; called by muse, mutect2, varscan2
- EPAS1 | c.932C>A p.A311E | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55385424; called by muse, mutect2, varscan2
- EPB41 | c.1402C>G p.P468A (on ENST00000343067 / NM_001166005.2; = p.P259A on NM_004437.4) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV58044443; called by muse, mutect2, varscan2
- EPHB3 | c.1480-1G>C p.X494_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV57805140; called by muse, mutect2, varscan2
- ERCC2 | c.816G>C p.R272S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV55539910; called by muse, mutect2
- ESRRB | c.399G>T p.G133= | Splice Region (SNP) | VAF 52/75 reads (69%) | catalogued as COSV55060130; called by muse, mutect2, varscan2
- ETF1 | c.812C>G p.S271C | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.366); catalogued as COSV62127174; called by muse, mutect2, varscan2
- EVI5L | c.1344G>C p.E448D | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54484756; called by muse, mutect2, varscan2
- F5 | c.3482G>T p.R1161L | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV63121871, COSV63122486; called by muse, mutect2, varscan2
- FAM135B | c.3320A>T p.K1107M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52715558; called by muse, mutect2, varscan2
- FAM47C | c.622T>A p.S208T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as COSV63725408; called by muse, mutect2, varscan2
- FAT3 | c.2009C>A p.S670* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV53092495, COSV53093860; called by muse, mutect2, varscan2
- FAT4 | c.9410G>T p.G3137V | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV58678026; called by muse, mutect2, varscan2
- FBXO24 | c.1429C>G p.L477V (on ENST00000241071 / NM_033506.3; = p.L515V on NM_012172.5) | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV99575023, COSV99575231; called by muse, mutect2
- FCER1G | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57154434; called by muse, mutect2, varscan2
- FCMR | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV65567451; called by muse, mutect2
- FN1 | c.5869G>A p.E1957K | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV60549407; called by muse, mutect2, varscan2
- FNDC7 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV54752224; called by muse, mutect2, varscan2
- FUT9 | c.573G>C p.W191C | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56144608; called by muse, mutect2, varscan2
- GALNT15 | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60216225; called by muse, mutect2, varscan2
- GALNT15 | c.308A>G p.Q103R | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60216236; called by muse, mutect2, varscan2
- GALNT7 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53928311; called by muse, mutect2, varscan2
- GCC2 | c.3283G>C p.A1095P | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as COSV59175215; called by muse, mutect2
- GLI2 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs1445852776, COSV58038327, COSV58049308; called by muse, mutect2, varscan2
- GLI3 | c.4211T>A p.L1404Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as COSV67886975; called by muse, mutect2, varscan2
- GNL3L | c.1263G>C p.M421I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV60575865; called by muse, mutect2, varscan2
- GOLGA1 | c.864G>C p.E288D | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1212273768, COSV65220980, COSV65221127, COSV65221396; called by muse, mutect2, varscan2
- GPR146 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.311); catalogued as rs1362390393, COSV52465834; called by muse, mutect2, varscan2
- GRM5 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV59591675, COSV59598882; called by muse, mutect2, varscan2
- GRM8 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs776267363, COSV58815922, COSV58846198; called by muse, mutect2, varscan2
- H2BC8 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as COSV55126191, COSV55126595; called by muse, mutect2
- H3C1 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); catalogued as COSV55119078; called by muse, mutect2, varscan2
- HAT1 | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.031); catalogued as COSV51362121; called by muse, mutect2, varscan2
- HEY1 | c.32C>A p.S11* | Nonsense Mutation (SNP) | VAF 40/144 reads (28%) | catalogued as COSV61232599; called by muse, mutect2, varscan2
- HOXB3 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 29/86 reads (34%) | catalogued as COSV57485942; called by muse, mutect2, varscan2
- HSPA12B | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs139568860; called by muse, mutect2, varscan2
- IAH1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV61070809; called by muse, mutect2, varscan2
- ICE1 | c.4444G>A p.E1482K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV56821906; called by muse, mutect2, varscan2
- IDH3B | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs760302966, COSV66482819, COSV66483108; called by muse, mutect2, varscan2
- IGLV2-33 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.626); catalogued as rs752483418; called by muse, mutect2, varscan2
- IKBKB | c.1557G>T p.Q519H | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV60596539; called by muse, mutect2, varscan2
- IL20RB | c.432G>C p.E144D | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.185); catalogued as COSV59047251; called by muse, mutect2, varscan2
- IRGQ | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.929); catalogued as COSV60670423; called by muse, mutect2, varscan2
- IVL | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV64215926, COSV64217104; called by muse, mutect2, varscan2
- JOSD1 | c.278C>A p.T93N | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.639); catalogued as COSV53265457; called by muse, mutect2, varscan2
- KCNB2 | c.2335G>T p.G779* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV73049581; called by muse, mutect2, varscan2
- KIAA1755 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV54075083; called by muse, mutect2, varscan2
- KIF11 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV53269655; called by muse, mutect2, varscan2
- KIF1B | c.3461C>T p.P1154L (on ENST00000377086 / NM_001365952.1; = p.P1108L on NM_015074.3) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55806211; called by muse, mutect2, varscan2
- KIF3B | c.1863-2A>G p.X621_splice | Splice Site (SNP) | VAF 9/22 reads (41%) | catalogued as COSV65227204; called by muse, mutect2, varscan2
- KMT2D | c.11377C>T p.Q3793* | Nonsense Mutation (SNP) | VAF 33/49 reads (67%) | catalogued as COSV56466640; called by muse, mutect2, varscan2
- KRT28 | c.1132G>C p.D378H | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100137698, COSV60684650; called by muse, mutect2, varscan2
- LIMCH1 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100573448; called by muse, mutect2, varscan2
- LIN28B | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.567); catalogued as COSV61494111; called by muse, mutect2, varscan2
- LRP2 | c.7783G>T p.A2595S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV55547569; called by muse, mutect2, varscan2
- LRRC1 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV63828545; called by muse, mutect2, varscan2
- LRSAM1 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.138); catalogued as COSV55939311; called by muse, mutect2, varscan2
- MAGEL2 | c.2465A>G p.Q822R | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV58566474; called by muse, mutect2, varscan2
- MAP2 | c.5329G>T p.E1777* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV52286492; called by muse, mutect2, varscan2
- MBD4 | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV51444302; called by muse, mutect2, varscan2
- MED12L | c.4319G>A p.G1440E | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56373956; called by muse, mutect2, varscan2
- METTL9 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | catalogued as COSV63961416; called by muse, mutect2, varscan2
- MEX3A | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.234); catalogued as COSV64141722; called by muse, mutect2, varscan2
- MEX3D | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as COSV66311903; called by muse, mutect2, varscan2
- MINAR1 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV100548674; called by muse, mutect2, varscan2
- MLH3 | c.4157C>T p.S1386L (on ENST00000355774 / NM_001040108.2; = p.S1362L on NM_014381.3) | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV53153627; called by muse, mutect2, varscan2
- MTR | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311934439, COSV100855659, COSV100855808; called by muse, mutect2
- MVB12B | c.604C>G p.Q202E | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV63257830; called by muse, mutect2, varscan2
- MYH8 | c.3805C>T p.Q1269* | Nonsense Mutation (SNP) | VAF 40/65 reads (62%) | catalogued as COSV67962544; called by muse, mutect2, varscan2
- MYO1H | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV60444282; called by muse, mutect2, varscan2
- MYO5B | c.2581G>C p.E861Q | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV53215237; called by muse, mutect2, varscan2
- NCR2 | c.231G>C p.W77C | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV66100564; called by muse, mutect2, varscan2
- NECTIN1 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as rs755806347, COSV50598637, COSV50602350; called by muse, mutect2, varscan2
- NEK2 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV65355612; called by muse, mutect2, varscan2
- NFE2L1 | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.901); catalogued as COSV62582879, COSV62582993; called by muse, mutect2, varscan2
- NOL4L | c.1160G>C p.S387T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV62889198; called by muse, mutect2, varscan2
- NOL9 | c.396+1G>A p.X132_splice | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as COSV60227495; called by muse, mutect2, varscan2
- NUP155 | c.243C>G p.I81M (on ENST00000231498 / NM_153485.3; = p.I22M on NM_004298.4) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.141); catalogued as COSV51528523; called by muse, mutect2, varscan2
- NUP188 | c.4379C>T p.S1460F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1297646936, COSV65330475, COSV65331529; called by muse, mutect2, varscan2
- OLFML3 | c.114G>A p.E38= | Splice Region (SNP) | VAF 21/38 reads (55%) | catalogued as COSV57435006; called by muse, mutect2, varscan2
- OR2A12 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as rs749631010, COSV68821215; called by muse, mutect2, varscan2
- OR2AT4 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.048); catalogued as COSV59406744; called by muse, mutect2, varscan2
- OR7C2 | c.137T>A p.I46N | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as COSV99934422; called by muse, mutect2, varscan2
- OSBP | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1565117241, COSV55661652; called by muse, mutect2, varscan2
- P2RY13 | c.233T>G p.F78C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56373945; called by muse, mutect2, varscan2
- PAK2 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505892; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1379G>A p.R460K (on ENST00000259318 / NM_001136562.3; = p.R691K on NM_007203.5) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52174851, COSV52180439; called by muse, mutect2, varscan2
- PCDHA10 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 108/213 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); catalogued as rs1168742927, COSV56474773, COSV56522919; called by muse, mutect2, varscan2
- PCDHGA3 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.066); catalogued as rs763074120, COSV53922327; called by muse, mutect2, varscan2
- PHOSPHO1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754585872, COSV56799655; called by muse, mutect2, varscan2
- PLAT | c.1061C>G p.S354C | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54274792; called by muse, mutect2, varscan2
- PLB1 | c.4169C>G p.S1390C | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59822352; called by muse, mutect2, varscan2
- PLXNB2 | c.3643G>T p.V1215L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV63780789; called by muse, mutect2
- PLXNC1 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51572883; called by muse, mutect2, varscan2
- PNCK | c.985C>A p.R329S (on ENST00000340888 / NM_001366975.1; = p.R412S on NM_001039582.3) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV61743108; called by muse, mutect2, varscan2
- PNMA5 | c.1270C>A p.P424T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV62625445; called by muse, mutect2, varscan2
- POLR3D | c.459G>C p.Q153H | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV60570869; called by muse, mutect2, varscan2
- PPP2R2D | c.489G>C p.L163F | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV70778769; called by muse, mutect2, varscan2
- PSD | c.2020A>T p.T674S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV50043480; called by muse, mutect2, varscan2
- PTGS2 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 61/170 reads (36%) | catalogued as COSV66568686, COSV66570357; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1076A>G p.D359G | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV51480611; called by muse, mutect2, varscan2
- RBBP6 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as COSV60504165; called by muse, mutect2, varscan2
- RBM39 | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as COSV53614630; called by muse, mutect2, varscan2
- RHPN1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV56645667; called by muse, mutect2, varscan2
- RPL31 | c.30G>T p.K10N | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV51821303; called by muse, mutect2, varscan2
- RREB1 | c.108C>A p.S36R | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as rs74933950, COSV58552938, COSV58555781; called by muse, mutect2, varscan2
- SDR16C5 | c.659T>C p.I220T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.468); catalogued as COSV58125959; called by muse, mutect2, varscan2
- SH3D21 | c.1952G>C p.R651T (on ENST00000453908 / NM_001162530.2; = p.R540T on NM_024676.5) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV54633868; called by muse, mutect2, varscan2
- SH3PXD2B | c.1564C>G p.L522V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV61125794; called by muse, mutect2, varscan2
- SLAMF8 | c.203T>A p.L68Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as COSV56987891; called by muse, mutect2, varscan2
- SLC3A2 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.287); catalogued as COSV58603162; called by muse, mutect2, varscan2
- SLC49A4 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV53746286, COSV53748397; called by muse, mutect2, varscan2
- SLC9A3 | c.2048G>A p.R683Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs755154955, COSV53800090; called by muse, mutect2, varscan2
- SLCO6A1 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV65808143; called by muse, mutect2
- SLITRK2 | c.1906G>A p.G636R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59424203, COSV59426819; called by muse, mutect2, varscan2
- SMCHD1 | c.4563C>G p.I1521M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV55254432; called by muse, mutect2, varscan2
- SNAPC4 | c.987C>G p.S329R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV100046639, COSV53732037; called by muse, mutect2, varscan2
- SNCAIP | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 21/31 reads (68%) | catalogued as COSV54406539, COSV54421329; called by muse, mutect2, varscan2
- SNRNP200 | c.4226C>T p.T1409I | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV60488554; called by muse, mutect2, varscan2
- SORBS3 | c.554A>G p.H185R | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV53552332; called by muse, mutect2, varscan2
- SP6 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as COSV60616999; called by muse, mutect2, varscan2
- SPHKAP | c.2052C>A p.H684Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV60873990; called by muse, mutect2, varscan2
- SRRT | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs1416060198, COSV61451680; called by muse, mutect2, varscan2
- SRRT | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.428); catalogued as COSV61451686; called by muse, mutect2, varscan2
- ST7 | c.1514C>G p.S505* (on ENST00000265437 / NM_021908.3; = p.S482* on NM_018412.4) | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV55382767; called by muse, mutect2, varscan2
- SYNCRIP | c.1598G>C p.R533T | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV62287257, COSV62289448; called by muse, mutect2, varscan2
- SZT2 | c.5384C>G p.S1795C (on ENST00000634258 / NM_001365999.1; = p.S1738C on NM_015284.4) | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT tolerated (0.05); PolyPhen benign (0.208); catalogued as COSV65168525; called by muse, mutect2, varscan2
- TAF1L | c.2053C>G p.R685G | Missense Mutation (SNP) | VAF 62/88 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54260040; called by muse, mutect2, varscan2
- TAS2R13 | c.145A>C p.I49L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV66831551; called by muse, mutect2, varscan2
- TFAP2A | c.884T>G p.V295G (on ENST00000482890; = p.V287G on NM_001032280.3) | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100116579, COSV60232369; called by muse, mutect2, varscan2
- THSD7B | c.1837T>C p.C613R | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773435535, COSV55671252, COSV55692023; called by muse, mutect2, varscan2
- TMC5 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV101196602; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4585G>T p.A1529S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV64100535, COSV64102942; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4297G>T p.A1433S | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV64100539; called by muse, mutect2, varscan2
- TNRC6C | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV56941992; called by muse, mutect2, varscan2
- TOMM40 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52976592; called by muse, mutect2, varscan2
- TRAPPC8 | c.2557G>C p.D853H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV51969052; called by muse, mutect2, varscan2
- TRIM17 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs750935063, COSV54381756; called by muse, mutect2, varscan2
- TRIM51 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs761280604, COSV55265331; called by muse, mutect2, varscan2
- TTC21A | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV57184130; called by muse, mutect2, varscan2
- USP20 | c.672C>G p.F224L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59612313; called by muse, mutect2, varscan2
- USP20 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs777596088, COSV59612333; called by muse, mutect2, varscan2
- UTRN | c.8548C>T p.Q2850* | Nonsense Mutation (SNP) | VAF 20/31 reads (65%) | catalogued as COSV62308705, COSV62309457; called by muse, mutect2, varscan2
- VDAC1 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV54737057; called by muse, mutect2, varscan2
- VDR | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV57467571; called by muse, mutect2, varscan2
- VPS13D | c.9274C>A p.H3092N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV99165580; called by muse, mutect2, varscan2
- XCL2 | c.129C>A p.S43R | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.067); catalogued as COSV63194123; called by muse, mutect2, varscan2
- ZBTB16 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV60091149; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2042G>A p.R681K | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54294527; called by muse, mutect2, varscan2
- ZNF143 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs775453952, COSV55179119; called by muse, mutect2, varscan2
- ZNF165 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs768075242, COSV66102208, COSV66102924; called by muse, mutect2, varscan2
- ZNF292 | c.303G>T p.L101F | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV60537335; called by muse, mutect2, varscan2
- ZNF358 | c.1553C>A p.P518Q | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.372); catalogued as COSV51174524; called by muse, mutect2, varscan2
- ZNF445 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs750830088, COSV68538672; called by muse, mutect2, varscan2
- ZNF519 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV73913258; called by muse, mutect2, varscan2
- ZNF551 | c.183C>A p.N61K | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56591991; called by muse, mutect2, varscan2
- ZNF565 | c.1141G>A p.G381R (on ENST00000355114; = p.G341R on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs750177810, COSV58410652, COSV58411628; called by muse, mutect2, varscan2
- ZNF620 | c.933C>A p.N311K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375417538, COSV58820209; called by muse, mutect2, varscan2
- ZNF624 | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100257049; called by muse, mutect2, varscan2
- ZNF648 | c.70C>G p.H24D | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV60570265; called by muse, mutect2, varscan2
- ZNF831 | c.80C>G p.P27R | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV64038784, COSV64044476; called by muse, mutect2, varscan2
- BEST1 | c.1390_1411del p.Y464Pfs*11 | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | called by mutect2, pindel, varscan2
- C22orf31 | c.343del p.A115Pfs*40 | Frame Shift Del (DEL) | VAF 29/79 reads (37%) | called by mutect2, pindel, varscan2
- GAB2 | c.367_369del p.E123del (on ENST00000361507 / NM_080491.3; = p.E85del on NM_012296.3) | In Frame Del (DEL) | VAF 8/56 reads (14%) | called by pindel, varscan2
- IGLV8-61 | c.225del p.Y75* | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- MYO18B | c.5744_5748+18del p.X1915_splice | Splice Site (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- NARF | c.1054_1101del p.I352_H367del | In Frame Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel
- NBPF9 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- RASAL2 | c.1968-15_1983del p.X656_splice | Splice Site (DEL) | VAF 18/106 reads (17%) | called by mutect2, pindel
- SLC4A9 | c.1830_1868del p.R611_T623del (on ENST00000507527 / NM_001258428.2; = p.R587_T599del on NM_031467.3) | In Frame Del (DEL) | VAF 29/43 reads (67%) | called by mutect2, pindel
- STOML3 | c.121_137del p.I41Hfs*9 | Frame Shift Del (DEL) | VAF 33/70 reads (47%) | called by mutect2, pindel, varscan2
- USP9X | c.3784_3810+3del p.X1262_splice | Splice Site (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- AC109583.1 | c.66C>T p.A22= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV59350474; called by muse, mutect2
- AHNAK2 | c.10755G>A p.L3585= | Silent (SNP) | VAF 40/68 reads (59%) | catalogued as rs370843314, COSV60911766, COSV60919204; called by muse, mutect2, varscan2
- ANKH | c.954A>C p.T318= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV52479043; called by muse, mutect2, varscan2
- APOL1 | c.546C>T p.L182= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as COSV59868747; called by muse, mutect2, varscan2
- ASTN1 | c.2043C>T p.L681= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs781083302, COSV56065610; called by muse, mutect2, varscan2
- CACNA1G | c.1311C>G p.L437= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV61723020; called by muse, mutect2, varscan2
- CEBPZ | c.2199C>A p.T733= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV52205566; called by muse, mutect2, varscan2
- COG4 | c.1506G>A p.R502= | Silent (SNP) | VAF 36/54 reads (67%) | catalogued as COSV60421904; called by muse, mutect2, varscan2
- COL3A1 | c.990T>A p.G330= | Silent (SNP) | VAF 51/105 reads (49%) | catalogued as COSV100482600, COSV100482833; called by muse, mutect2, varscan2
- CPSF6 | c.393T>C p.V131= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV57013503; called by muse, mutect2, varscan2
- DMXL2 | c.4599C>T p.F1533= | Silent (SNP) | VAF 41/56 reads (73%) | catalogued as COSV51843172; called by muse, mutect2, varscan2
- E2F3 | c.438C>G p.L146= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as COSV100685796; called by muse, mutect2, varscan2
- EGFL8 | c.141C>G p.L47= | Silent (SNP) | VAF 30/50 reads (60%) | catalogued as COSV61247329; called by muse, mutect2, varscan2
- EHD1 | c.696G>C p.V232= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV57734139; called by muse, mutect2, varscan2
- ENPP2 | c.1794C>G p.L598= (on ENST00000075322 / NM_001040092.3; = p.L650= on NM_006209.5) | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV50012003; called by muse, mutect2, varscan2
- ERC2 | c.2493C>T p.A831= | Silent (SNP) | VAF 70/171 reads (41%) | catalogued as rs191615919, COSV99881730; called by muse, mutect2, varscan2
- FDPS | c.675C>G p.L225= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV63114198; called by muse, mutect2, varscan2
- FN1 | c.7071C>T p.Y2357= (on ENST00000359671 / NM_001365524.2; = p.Y2326= on NM_002026.4) | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV60549393; called by muse, mutect2, varscan2
- FUT5 | c.543C>A p.P181= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV53135660; called by muse, mutect2, varscan2
- FZD5 | c.432G>A p.E144= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs746545049, COSV54943232; called by muse, mutect2, varscan2
- GPKOW | c.87G>A p.R29= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV50242309, COSV99332439; called by muse, mutect2, varscan2
- GPR143 | c.393C>T p.F131= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV66631883; called by muse, mutect2, varscan2
- GPR37 | c.411G>A p.G137= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV58256192; called by muse, mutect2, varscan2
- GRIK4 | c.1377C>G p.L459= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs769829036, COSV70801296; called by muse, mutect2, varscan2
- GSE1 | c.1815G>A p.L605= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as COSV99496136; called by muse, mutect2, varscan2
- HHATL | c.1216C>T p.L406= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV55133642; called by muse, mutect2
- HIPK4 | c.411C>G p.L137= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs766701110, COSV52520100; called by muse, mutect2, varscan2
- HORMAD2 | c.594C>T p.L198= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1413041722, COSV60898016; called by muse, mutect2, varscan2
- INHBA | c.717C>T p.D239= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs370035610; called by muse, mutect2, varscan2
- INTS1 | c.6199C>T p.L2067= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV67176945; called by muse, mutect2, varscan2
- KCND2 | c.1221C>A p.S407= | Silent (SNP) | VAF 44/87 reads (51%) | catalogued as COSV58574811; called by muse, mutect2, varscan2
- KIAA0319L | c.2715C>A p.I905= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV100356949; called by muse, mutect2
- KIF19 | c.2673G>T p.R891= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV63429178; called by muse, mutect2, varscan2
- LHX3 | c.36G>A p.A12= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as rs1451358680, COSV62393765; called by muse, mutect2, varscan2
- LRP5 | c.3399G>C p.L1133= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV53713622; called by muse, mutect2, varscan2
- MEX3C | c.639G>A p.A213= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV68529742; called by muse, mutect2, varscan2
- MIS18A | c.384T>G p.R128= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV51588924, COSV99267150; called by muse, mutect2, varscan2
- NEK10 | c.201T>C p.G67= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV58281789; called by muse, mutect2, varscan2
- NME8 | c.1569G>A p.L523= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV52248541, COSV99553513; called by muse, mutect2
- NR5A2 | c.57A>T p.T19= | Silent (SNP) | VAF 59/91 reads (65%) | catalogued as COSV99370734; called by muse, mutect2, varscan2
- NRXN2 | c.1953G>C p.R651= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV55450488; called by muse, mutect2, varscan2
- NTNG2 | c.525C>T p.F175= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs889123876, COSV62365851; called by muse, mutect2, varscan2
- OAZ2 | c.384G>A p.E128= | Silent (SNP) | VAF 12/14 reads (86%) | catalogued as COSV58106531, COSV58107464; called by muse, mutect2, varscan2
- OR10J3 | c.630A>T p.L210= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV59953979; called by muse, mutect2, varscan2
- OR51I1 | c.558C>T p.L186= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV66507608; called by muse, mutect2, varscan2
- PCDHA12 | c.1362G>A p.A454= | Silent (SNP) | VAF 82/154 reads (53%) | catalogued as COSV56481412; called by muse, mutect2, varscan2
- PCDHB8 | c.1998C>A p.G666= | Silent (SNP) | VAF 84/173 reads (49%) | catalogued as COSV50759784; called by muse, mutect2, varscan2
- PDK3 | c.561C>A p.I187= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV64793167; called by muse, mutect2, varscan2
- PDZD2 | c.7455G>C p.L2485= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV56854914; called by muse, mutect2, varscan2
- PI4KA | c.624C>G p.L208= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1470651331, COSV55407873; called by muse, mutect2, varscan2
- PLCD3 | c.675C>A p.L225= | Silent (SNP) | VAF 40/50 reads (80%) | catalogued as COSV59559258; called by muse, mutect2, varscan2
- PLEKHG4 | c.1050G>A p.L350= | Silent (SNP) | VAF 25/34 reads (74%) | catalogued as COSV64612226; called by muse, mutect2, varscan2
- PLXNB2 | c.3645G>T p.V1215= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV63780786; called by muse, mutect2
- PRR12 | c.2259C>T p.F753= (on ENST00000615927; = p.F1574= on NM_020719.3) | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as rs775218037, COSV69817131; called by muse, mutect2, varscan2
- PTGFRN | c.2025C>T p.L675= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV67798123; called by muse, mutect2, varscan2
- RAB3IP | c.624A>G p.E208= (on ENST00000550536 / NM_175623.4; = p.E192= on NM_022456.5) | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV99922974; called by muse, mutect2, varscan2
- RBAK | c.1284C>G p.P428= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs769335141, COSV62331122; called by muse, mutect2, varscan2
- RELN | c.6093T>A p.T2031= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV58994163; called by muse, mutect2, varscan2
- RNF133 | c.564T>C p.N188= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV57356583; called by muse, mutect2, varscan2
- RNF8 | c.678A>G p.K226= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100009398; called by muse, mutect2, varscan2
- RPL7 | c.720C>T p.I240= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV53581866; called by muse, mutect2, varscan2
- RXRB | c.96C>T p.V32= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs1415133782, COSV63399606; called by mutect2, varscan2
- SAE1 | c.621C>G p.V207= | Silent (SNP) | VAF 26/36 reads (72%) | catalogued as COSV54294099, COSV54296588; called by muse, mutect2, varscan2
- SASH1 | c.1252C>T p.L418= | Silent (SNP) | VAF 42/58 reads (72%) | catalogued as rs370605056; called by muse, mutect2, varscan2
- SEC16B | c.1704C>G p.L568= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100381296; called by muse, mutect2, varscan2
- SLC15A1 | c.1387C>T p.L463= | Silent (SNP) | VAF 40/63 reads (63%) | catalogued as COSV64730635; called by muse, mutect2, varscan2
- SLIT3 | c.918G>A p.P306= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs147887398; called by muse, mutect2, varscan2
- SPTLC1 | c.6G>T p.A2= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as COSV52763472; called by muse, mutect2, varscan2
- SYT5 | c.388C>T p.L130= | Silent (SNP) | VAF 29/43 reads (67%) | catalogued as COSV100845868, COSV62829595; called by muse, varscan2
- TJP3 | c.1452T>C p.F484= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99515816; called by muse, mutect2
- TMEM163 | c.869G>A p.*290= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV56105222; called by muse, mutect2, varscan2
- TMEM74B | c.231G>A p.G77= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs1568494103, COSV67891802; called by muse, mutect2, varscan2
- TRIM55 | c.1014C>T p.G338= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs759446548, COSV52544981; called by muse, mutect2, varscan2
- UBXN2A | c.420A>T p.L140= | Silent (SNP) | VAF 44/61 reads (72%) | catalogued as COSV58336015; called by muse, mutect2, varscan2
- USPL1 | c.780G>A p.S260= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs778232932, COSV54998756, COSV54999434; called by muse, mutect2, varscan2
- USPL1 | c.1254C>T p.F418= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV54999304; called by muse, mutect2, varscan2
- VGLL4 | c.492G>A p.V164= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as COSV56075901; called by muse, mutect2, varscan2
- WNT4 | c.351G>A p.S117= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs773452719, COSV51603160; called by muse, mutect2, varscan2
- ZC3H7A | c.2049G>A p.Q683= | Silent (SNP) | VAF 24/26 reads (92%) | catalogued as COSV100865463; called by muse, mutect2, varscan2
- ZDBF2 | c.1704C>T p.T568= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV65623681; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840345 C>A | 5'Flank (SNP) | VAF 30/77 reads (39%) | catalogued as COSV58331590; called by muse, mutect2, varscan2
- AP4B1 | c.-1G>C | 5'UTR (SNP) | VAF 21/57 reads (37%) | catalogued as COSV56724165; called by muse, mutect2, varscan2
- ASCC1 | c.*143C>A | 3'UTR (SNP) | VAF 3/50 reads (6%) | catalogued as COSV100403139; called by muse, mutect2
- BSDC1 | c.1260+40G>T | Intron (SNP) | VAF 26/34 reads (76%) | catalogued as COSV61981711; called by muse, mutect2, varscan2
- FBXL21P | n.1261T>C | RNA (SNP) | VAF 27/44 reads (61%) | catalogued as COSV99778208; called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6049857 C>T | 3'Flank (SNP) | VAF 23/31 reads (74%) | catalogued as COSV51526366; called by muse, mutect2, varscan2
- MUTYH | c.36+303C>A | Intron (SNP) | VAF 17/27 reads (63%) | catalogued as COSV100517099; called by muse, mutect2, varscan2
- PIK3C2B | c.934-1548C>G | Intron (SNP) | VAF 33/93 reads (35%) | called by muse, mutect2, varscan2
- POLA1 | c.2947-21500C>G | Intron (SNP) | VAF 10/30 reads (33%) | catalogued as rs1271013933; called by muse, mutect2, varscan2
- UBE2D2 | c.24+530C>T | Intron (SNP) | VAF 32/62 reads (52%) | catalogued as COSV99551302; called by muse, mutect2, varscan2
- XIRP2 | c.*737G>A | 3'UTR (SNP) | VAF 6/13 reads (46%) | catalogued as COSV54691283; called by muse, mutect2, varscan2
- XIRP2 | c.*1360A>T | 3'UTR (SNP) | VAF 36/96 reads (38%) | catalogued as COSV54691293; called by muse, mutect2, varscan2
